Somatic mutation profile of tumor specimen TCGA-FG-6690-01A (aliquot TCGA-FG-6690-01A-11D-1893-08) from TCGA case TCGA-FG-6690, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 70.3 years (25,667 days).
Specimen TCGA-FG-6690-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbc9428d-73a9-4682-8143-505847b8b9b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-6690-10A (Blood Derived Normal), aliquot TCGA-FG-6690-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b07c9f3c-0d36-46b1-9f9e-e69cbd8ef7e5

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATAD1 | c.649A>C p.M217L | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57756607; called by muse, mutect2
- ATP4A | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV52867413; called by muse, mutect2, varscan2
- ATRX | c.1226T>A p.L409* | Nonsense Mutation (SNP) | VAF 242/304 reads (80%) | catalogued as CM056937, COSV64875194; called by muse, mutect2, varscan2
- BPTF | c.2930G>A p.R977Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58835894; called by muse, mutect2, varscan2
- CCNB1IP1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1349838412, COSV62302691; called by muse, mutect2
- DNAH8 | c.12620A>G p.K4207R | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59440370; called by muse, mutect2, varscan2
- FRYL | c.7867G>A p.V2623I | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as rs1560519592, COSV51945253; called by muse, mutect2
- ITGA11 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59876981; called by muse, mutect2, varscan2
- KRT76 | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60119950; called by muse, mutect2, varscan2
- MUC21 | c.1001A>T p.E334V | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV66220016, COSV66220653; called by muse, mutect2
- MYH2 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV55436292; called by muse, mutect2, varscan2
- PANK4 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs757608469, COSV53941839; called by muse, mutect2, varscan2
- PHF10 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV59321808; called by muse, mutect2
- REM2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs1204230900, COSV57465448; called by muse, mutect2, varscan2
- RIOK3 | c.1302C>A p.H434Q | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as COSV59772031, COSV59772775; called by muse, mutect2, varscan2
- SCN8A | c.5569G>A p.G1857R | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61980122; called by muse, mutect2
- SMARCA4 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs371214327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPEN | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65360870; called by muse, mutect2
- TNFSF15 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150498686; called by muse, mutect2, varscan2
- ZNF831 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs771540309, COSV64039355; called by muse, mutect2, varscan2
- ZZZ3 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs750971669, COSV66232362; called by muse, mutect2, varscan2
- ATXN2L | c.2790T>C p.P930= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV57368902; called by muse, mutect2, varscan2
- CDC42BPB | c.2706C>T p.D902= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs749875982, COSV63474709; called by muse, mutect2, varscan2
- NCAM1 | c.390G>A p.R130= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV57514913; called by muse, mutect2
- NPAT | c.1782T>C p.N594= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as rs192893789; called by muse, mutect2
